Somatic mutation profile of tumor specimen TCGA-L6-A4EP-01A (aliquot TCGA-L6-A4EP-01A-11D-A257-08) from TCGA case TCGA-L6-A4EP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.9 years (15,292 days).
Specimen TCGA-L6-A4EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f0238db-cd25-4a6a-91a2-af2fdfaeb9f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L6-A4EP-10A (Blood Derived Normal), aliquot TCGA-L6-A4EP-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e3420b9-def7-4bec-9ab6-d168e1c70ea9

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATG12 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs749744688, COSV57243330; called by muse, mutect2
- GFAP | c.1240G>C p.V414L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.631); catalogued as rs749236721, COSV53651540; called by muse, mutect2, varscan2
- HUWE1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs782606768, COSV53351476; called by mutect2, varscan2
- NDUFS1 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51910993; called by muse, mutect2
- OR2AT4 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59407160; called by muse, mutect2, varscan2
- SDC2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56225736; called by muse, mutect2
- SF3B1 | c.2626A>T p.M876L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59206800, COSV59218224; called by muse, mutect2, varscan2
- TESPA1 | c.1457A>G p.D486G (on ENST00000316577 / NM_001098815.3; = p.D348G on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.384); catalogued as COSV57259657; called by muse, mutect2
- ANKRD53 | c.294G>A p.Q98= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs782533666, COSV55537852; called by muse, mutect2, varscan2
